Surgical pathology report (de-identified scan), TCGA case TCGA-99-8025, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-8025-01A (Primary Tumor).

[page 1 of 3]
Patient Name

MR#

Observation Date

Last Edited Date

SURGICAL PATHOLOGY CASE:

Diagnosis

Lymph node, level IX, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, level VIII, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, level X, excision:

- Multiple fragments of lymph node negative for malignancy.

Lymph node, level VII, excision:

- Multiple fragments of lymph node negative for malignancy.

Lymph node, level XI, excision:

- Multiple fragments of lymph node negative for malignancy.

Lung, right upper lobe, bronchial margin:

- Negative for malignancy.

Lung, right upper lobe, resection:

- Adenocarcinoma, moderately differentiated with bronchoalveolar features.
- Two tumor nodules are present, measuring 5.5 cm and 1.0 cm.
- Tumor involves peribronchial soft tissue and perineural invasion is identified.
- Overlying pleura is uninvolved by tumor.
- Adenocarcinoma is present in shaved stapled line.
- One lymph node negative for malignancy (0/1).
- Pathologic stage: pT3(m) / N2.

Lymph node, level II, excision:

- One lymph node negative for malignancy (0/1).

Lymph node, level IV, excision:

- One lymph node positive for metastatic carcinoma (1/3).

Clinical Information

The patient is a [REDACTED] year old female with a history of lung cancer.

Frozen Section Diagnosis

FFS1: Bronchial margin, biopsy:

- Negative for malignancy.

GFS1: Lung, right upper lobe, resection:

- Non-small cell carcinoma with squamous features. (per Dr.)

Gross Description

The specimen is received in nine separate containers, all labeled with the

[page 2 of 3]
patient's name and medical record number.

Specimen #1 is received in formalin and is designated as "#1 level IX lymph node". Received is a single fragment of tan-black lymph node tissue measuring 1.2 x 0.4 x 0.4 cm. It is entirely submitted in one cassette.

Specimen #2 is received in formalin and is designated as "#2 level VIII lymph node". Received is a single fragment of yellow and black lymphoadipose tissue measuring 1.0 x 0.6 x 0.3 cm. It is entirely submitted in one cassette.

Specimen #3 is received in formalin and is designated as "#3 level X lymph node". Received are multiple fragments of tan and black lymphoadipose tissue measuring in aggregate 1.6 x 0.8 x 0.3 cm. The fragments are entirely submitted in one cassette.

Specimen #4 is received in formalin and is designated as "#2 level VII lymph node". Received are multiple fragments of tan and black lymphoadipose tissue measuring in aggregate 1.7 x 1.4 x 0.5 cm. They are entirely submitted in one cassette.

Specimen #5 is received in formalin and is designated as "#5 level XI lymph node". Received are multiple fragments of brown and black tissue measuring in aggregate 1.1 x 0.7 cm. The specimen is serially sectioned and entirely submitted in one cassette.

Specimen #6 was previously received for frozen section. At that time it was noted to consist of two fragments of tissue measuring 1.0 x 0.5 x 0.3 cm, and 0.8 x 0.4 x 0.3 cm. It was entirely submitted for frozen section and is now entirely submitted for permanent section.

Specimen #7 is received in a container labeled "#7 - right upper lobe". This was initially received fresh for frozen section and is now received in formalin. The specimen consists of a 10.0 x 6.5 x 5.0 cm lobe of lung. At the time of frozen section, a 5.5 x 4.5 x 3.8 cm tan mass with anthracotic pigment and an infiltrative border was described 1.0 cm from the stapled margin. Also, a separate 1.0 cm nodule was noted, 2.0 cm from the stapled margin. A representative section of the larger lesion taken at the time of frozen will be resubmitted for permanent. Sectioning through the tumor reveals that it encircles the more proximal portion of the bronchus on the specimen. The most distal aspect appears free of tumor. A segment of vessel is identified next to the bronchus and the margin is shaved and submitted. The additionally described separate nodule is at least 2.0 cm from the stapled surgical margin. The lung is serially sectioned and no additional lesions are identified. The uninvolved lung parenchyma is tan-purple. The stapled surgical margin is shaved and submitted.

Specimen #8 is received in formalin labeled "#8 level II lymph node". Received is a single fragment of yellow lobular adipose tissue measuring 1.0 x 0.5 x 0.5 cm. It is entirely submitted in one cassette. Specimen #9 is received in formalin and is designated as "#9 level IV lymph node". Received are multiple fragments of tan-white tissue measuring 2.5 x 1.0 x 0.8 cm. The fragments are entirely submitted in one cassette.

Block Summary

- A1 - Level IX lymph node
- B1 - Level VIII lymph node
- C1 - Level X lymph node
- D1 - Level VII lymph node
- E1 - Level XI lymph node
- F1 - Bronchial margin
- G1- Representative section of lung (frozen section).
- G2- Additional bronchial tissue.
- G3- Tumor in relationship to uninvolved lung.
- G4-G5- Tumor in relationship to bronchus.
- G6- Vascular margin with additional representative sections of the tumor.
- G7- Representative section of the tumor.
- G8- Representative sections from separate smaller lesion.
- G9-G12- Shaved stapled surgical margin.
- H1 - Level II lymph node

[page 3 of 3]
11 - Level I lymph node

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report

G: Thorax Lung

SPECIMEN:

Lobe(s) of lung: Right upper lobe

PROCEDURE:

Lobectomy

SPECIMEN INTEGRITY:

Intact

SPECIMEN LATERALITY:

Right

TUMOR SITE:

Upper lobe

TUMOR SIZE:

Greatest dimension: 5.5 cm

TUMOR FOCALITY:

Separate tumor nodules in same lobe

HISTOLOGIC TYPE:

Adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

VISCERAL PLEURA INVASION:

Not identified

BRONCHIAL MARGIN:

Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION:

Not identified

PRIMARY TUMOR (pT):

pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium;

or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe

REGIONAL LYMPH NODES (pN):

pN2: Metastasis in ipsilateral mediastinal and/or subcarinal lymph node(s)

Source: NCI Genomic Data Commons file ae26bf90-1315-45ae-ae8e-a6bc40f8492b (TCGA-99-8025.42373413-46DF-4837-A01F-2659D92888CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).